Somatic mutation profile of tumor specimen TCGA-IA-A40Y-01A (aliquot TCGA-IA-A40Y-01A-11D-A25F-10) from TCGA case TCGA-IA-A40Y, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 60.2 years (21,996 days).
Specimen TCGA-IA-A40Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29cd4e64-c3b6-4003-a54c-fc8dc36fa2c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IA-A40Y-10A (Blood Derived Normal), aliquot TCGA-IA-A40Y-10A-01D-A25F-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b8129b4-74ff-4715-bb0a-1a296ca87156

The open-access MAF lists 79 somatic variants for this specimen: 60 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 17, Nonsense Mutation 2, Frame Shift Del 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RYR2 | c.14704C>T p.P4902S | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs794728808, CM097974, COSV63670085, COSV63682207; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.1713C>G p.S571R | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.114); catalogued as COSV59384011; called by muse, mutect2, varscan2
- AHCY | c.1076G>A p.S359N | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.515); catalogued as COSV54152687; called by muse, mutect2, varscan2
- BMI1 | c.756C>G p.D252E | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.045); catalogued as COSV64958789; called by muse, mutect2, varscan2
- BPTF | c.8822G>T p.R2941L | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV58833105; called by muse, mutect2
- CBX4 | c.1555C>G p.P519A | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.018); catalogued as COSV53964727; called by muse, mutect2
- CCDC88A | c.2233A>C p.K745Q | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as COSV55058128; called by muse, varscan2
- CCNE2 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV57375178; called by muse, mutect2, varscan2
- CEBPZ | c.2912A>T p.N971I | Missense Mutation (SNP) | VAF 70/192 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.07); catalogued as COSV52205295; called by muse, mutect2, varscan2
- CEP131 | c.2684G>T p.G895V (on ENST00000269392 / NM_001319228.2; = p.G892V on NM_014984.4) | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV53951245; called by muse, mutect2, varscan2
- CEP162 | c.703G>A p.G235S | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV57618202, COSV57623566; called by muse, mutect2, varscan2
- CFTR | c.3601G>T p.D1201Y | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as rs1182767623, COSV50043274, COSV50084343; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRM3 | c.1705C>T p.R569C | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs779263285, COSV55083343; called by muse, mutect2
- CKB | c.20A>C p.H7P | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV62379396; called by muse, mutect2, varscan2
- CLTC | c.766G>T p.A256S | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as COSV52245642; called by muse, mutect2
- CUBN | c.7426C>T p.R2476W | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs774063108, COSV64709990; called by muse, mutect2, varscan2
- DDX4 | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61754038; called by muse, mutect2
- DNAH5 | c.9387C>A p.F3129L | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV54210279; called by muse, mutect2
- DNMT3A | c.2504C>T p.T835M | Missense Mutation (SNP) | VAF 81/252 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1489843853, COSV53041391; called by muse, mutect2, varscan2
- FLT4 | c.1540A>T p.K514* | Nonsense Mutation (SNP) | VAF 21/193 reads (11%) | catalogued as COSV56101429; called by muse, mutect2
- GRAMD1A | c.1544C>T p.S515L | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as rs777238052, COSV58766203; called by muse, mutect2, varscan2
- GUCY1B1 | c.1508T>G p.M503R | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV52374163; called by muse, mutect2, varscan2
- H2AC8 | c.21A>T p.Q7H | Missense Mutation (SNP) | VAF 63/121 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV55126403; called by muse, mutect2, varscan2
- HDDC2 | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 78/165 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as rs760973546, COSV59531949; called by muse, mutect2, varscan2
- HEATR5A | c.5710T>C p.C1904R | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV66339104; called by muse, mutect2
- HECTD1 | c.5918G>A p.S1973N | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs762748615, COSV67945440; called by muse, mutect2, varscan2
- ITPRID1 | c.279G>T p.M93I | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV60071589; called by muse, mutect2, varscan2
- KLB | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV57300586; called by muse, mutect2, varscan2
- KMT2D | c.9151G>C p.A3051P | Missense Mutation (SNP) | VAF 56/243 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56419732, COSV99985606; called by muse, mutect2, varscan2
- OR4D9 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61434282; called by muse, mutect2, varscan2
- OR4S1 | c.852C>G p.I284M | Missense Mutation (SNP) | VAF 8/167 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60678821, COSV60678824; called by muse, mutect2
- OR6A2 | c.835G>T p.V279F | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369095527; called by muse, mutect2, varscan2
- PARP10 | c.1106G>C p.G369A | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as COSV57297025; called by muse, mutect2, varscan2
- PCDHGA1 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.055); catalogued as COSV65295349; called by muse, mutect2, varscan2
- PHF19 | c.1490G>A p.R497H | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.613); catalogued as rs144405933; called by muse, mutect2, varscan2
- PLEKHM3 | c.2033G>C p.S678T | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.521); catalogued as COSV66815864; called by muse, mutect2
- POLR2B | c.2666A>T p.K889M | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58899070; called by muse, mutect2
- RAC2 | c.328A>T p.I110F | Missense Mutation (SNP) | VAF 78/211 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.175); catalogued as COSV50773960; called by muse, mutect2, varscan2
- RAD51AP2 | c.499A>C p.I167L | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV67587265; called by muse, mutect2, varscan2
- SCN11A | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 99/129 reads (77%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs777219461, COSV56567195; called by muse, mutect2, varscan2
- SEPTIN6 | c.191A>T p.N64I | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1391918744, COSV59712981; called by muse, mutect2, varscan2
- SERPINB3 | c.1089C>G p.F363L | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as COSV52190192; called by muse, varscan2
- SF3B1 | c.2540C>T p.A847V | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV59209544; called by muse, mutect2, varscan2
- SHMT2 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV61073400; called by muse, mutect2, varscan2
- SLCO2B1 | c.251G>T p.S84I | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56933602; called by muse, mutect2
- SNX10 | c.233C>G p.S78C | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as COSV58400453; called by muse, mutect2
- SPTA1 | c.5690A>G p.K1897R | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV63750173; called by muse, mutect2, varscan2
- SRSF6 | c.928T>G p.S310A | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs1354137088, COSV54827166; called by muse, mutect2, varscan2
- SYNE2 | c.8486T>G p.L2829* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV59942502; called by muse, mutect2, varscan2
- TAS1R2 | c.749C>T p.T250M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as rs79635934, COSV64743865; called by muse, mutect2, varscan2
- TCP11L2 | c.708C>G p.H236Q | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.3); catalogued as COSV54429252; called by muse, mutect2, varscan2
- TENM4 | c.4404G>T p.E1468D | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); catalogued as COSV53614857; called by muse, mutect2, varscan2
- TRIM8 | c.155G>C p.C52S | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56659872; called by muse, mutect2, varscan2
- TRPV4 | c.1184C>T p.T395M | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.475); catalogued as rs374197231; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTC24 | c.938G>C p.G313A | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.876); catalogued as COSV63997356; called by muse, mutect2, varscan2
- TTN | c.49329G>C p.L16443F (on ENST00000591111; = p.L9019F on NM_003319.4) | Missense Mutation (SNP) | VAF 40/225 reads (18%) | PolyPhen probably damaging (0.999); catalogued as COSV59933320; called by muse, mutect2, varscan2
- VCAM1 | c.1570C>G p.L524V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs1410765393, COSV54118222; called by muse, mutect2, varscan2
- ZNF585B | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1405908614, COSV57214773; called by muse, mutect2
- IFT74 | c.99_111del p.N34Qfs*18 | Frame Shift Del (DEL) | VAF 16/35 reads (46%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.3410G>A p.R1137K | Missense Mutation (SNP) | VAF 14/313 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.099); called by muse, mutect2
- AADACL2 | c.1104T>C p.D368= | Silent (SNP) | VAF 14/189 reads (7%) | catalogued as COSV62929746; called by muse, mutect2
- ALAD | c.189G>A p.E63= | Silent (SNP) | VAF 5/114 reads (4%) | catalogued as rs1419766313, COSV52958207; called by muse, mutect2
- DGKD | c.2766C>T p.V922= (on ENST00000264057 / NM_152879.3; = p.V878= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/131 reads (6%) | catalogued as COSV51035411; called by muse, mutect2
- DNAH2 | c.6285C>T p.R2095= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as rs1353160487, COSV66717479; called by muse, mutect2
- FAM222A | c.1296G>A p.T432= | Silent (SNP) | VAF 18/206 reads (9%) | catalogued as rs138993259; called by muse, mutect2
- FATE1 | c.264G>A p.L88= | Silent (SNP) | VAF 36/246 reads (15%) | catalogued as COSV64848892; called by muse, mutect2, varscan2
- FIP1L1 | c.9C>T p.A3= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs763328622, COSV60994540; called by muse, mutect2
- HHIPL2 | c.1059C>T p.F353= | Silent (SNP) | VAF 10/212 reads (5%) | catalogued as COSV58563700; called by muse, mutect2
- IGSF22 | c.1140T>C p.D380= | Silent (SNP) | VAF 100/344 reads (29%) | catalogued as rs1275865265, COSV60031816; called by muse, mutect2, varscan2
- MYH8 | c.4314T>A p.S1438= | Silent (SNP) | VAF 18/225 reads (8%) | catalogued as COSV67961338; called by muse, mutect2
- NALCN | c.1509A>G p.G503= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV51923215; called by muse, mutect2, varscan2
- PFKFB3 | c.132C>T p.P44= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as rs146319524; called by muse, mutect2, varscan2
- PGLYRP2 | c.138C>A p.T46= | Silent (SNP) | VAF 18/118 reads (15%) | catalogued as COSV52992055; called by muse, mutect2, varscan2
- PKHD1 | c.4818C>T p.V1606= | Silent (SNP) | VAF 9/207 reads (4%) | catalogued as COSV61860468, COSV61864906; called by muse, mutect2
- RCBTB1 | c.375C>G p.L125= | Silent (SNP) | VAF 41/195 reads (21%) | catalogued as COSV51633594; called by muse, mutect2, varscan2
- SLCO6A1 | c.873C>T p.V291= | Silent (SNP) | VAF 4/82 reads (5%) | catalogued as COSV65806623; called by muse, mutect2
- SMTN | c.357G>C p.R119= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV100294293, COSV60776049; called by muse, mutect2, varscan2
- SIGLEC1 | c.*14C>T | 3'UTR (SNP) | VAF 28/192 reads (15%) | catalogued as rs1215173755; called by muse, mutect2, varscan2
- TECR | c.563-27G>C | Intron (SNP) | VAF 40/176 reads (23%) | called by muse, mutect2, varscan2
